Somatic mutation profile of tumor specimen BA2446D (aliquot aq-BA2446D) from BEATAML1.0 case 2429, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.7 years (11,205 days).
Specimen BA2446D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5c8c3fa-18c2-4c73-8ef8-57478b272181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3016D (Solid Tissue Normal), aliquot aq-BA3016D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4ec0d88-fd43-4694-8e82-acf6ce1fdf9f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTUS2 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV70917866; called by muse, mutect2, varscan2
- SHANK2 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782002202, COSV58325993; called by muse, mutect2, varscan2
- KIAA2012 | c.3271C>T p.R1091* | Nonsense Mutation (SNP) | VAF 48/200 reads (24%) | called by muse, varscan2
- STEAP3 | c.213G>A p.A71= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs372757046; called by muse, mutect2, varscan2
- UNC93A | c.981G>A p.A327= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs753203183, COSV57809171; called by muse, mutect2, varscan2
- ZNF461 | c.159C>T p.A53= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs779475299, COSV64454353; called by mutect2, varscan2
